Somatic mutation profile of tumor specimen MP2PRT-PAPEJM-TBP1-A (aliquot MP2PRT-PAPEJM-TBP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPEJM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,344 days).
Specimen MP2PRT-PAPEJM-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0ca984b-baba-43d2-a5de-3988e94905f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPEJM-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPEJM-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e31b11f1-1dbe-4fd0-8f19-981df3f8ed48

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, 3'Flank 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN10 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 33/347 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.363); catalogued as COSV65296426; called by muse, mutect2
- CRACD | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as rs373181510; called by muse, mutect2
- DSG4 | c.2977G>A p.G993S | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs1412936496; called by muse, mutect2, varscan2
- IFNE | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 27/492 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1423733096, COSV100438850; called by muse, mutect2
- OR2A12 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68821111, COSV99065255; called by muse, mutect2
- OR8J2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs764955410; called by muse, mutect2
- SERPINI2 | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV52985475; called by muse, mutect2
- TMEM130 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs149015420; called by muse, mutect2
- ABCC9 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 49/379 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- HTRA1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 48/524 reads (9%) | called by muse, mutect2
- OFD1 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PIP4K2A | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); called by muse, mutect2
- PPP1R3F | c.1031A>G p.K344R | Missense Mutation (SNP) | VAF 34/395 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- RANBP2 | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2
- ACSBG2 | c.112C>T p.L38= | Silent (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- IL1RAP | chr3:190656181 G>C | 3'Flank (SNP) | VAF 25/305 reads (8%) | called by muse, mutect2
